Somatic mutation profile of tumor specimen 0DELKN from CCDI case PBBLPX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.8 years (1,759 days).
Specimen 0DELKN: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5e8091b-7424-4551-930c-71a36024a58e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DELJ6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e98fc2d8-8a76-4ebc-8700-148c3b6c25f7

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 2, Splice Site 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, varscan2
- AMER1 | c.1987G>C p.V663L | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.444); catalogued as COSV57662870; called by muse, varscan2
- GLO1 | c.467-1G>T p.X156_splice | Splice Site (SNP) | VAF 24/233 reads (10%) | called by muse, varscan2
- GLO1 | c.467-2A>C p.X156_splice | Splice Site (SNP) | VAF 24/232 reads (10%) | called by muse, varscan2
- ALKBH8 | c.1038G>A p.P346= | Silent (SNP) | VAF 48/190 reads (25%) | catalogued as rs188523089; called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs1167537044; called by muse, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99987084; called by muse, varscan2
- ZFYVE16 | c.3607+79C>T | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, varscan2
